Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A969, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A969-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

Pathology Report-Summary:

Material:

Tumor: 6.0 x 6.0 x 4.0 cm

focal infiltration of lung parenchyma and pericard

Diagnosis:

Thymic carcinoma

pT3, pN0 (0/10), pM1

Masaoka-Koga: IVb

Immunohistochemistry

epithelial cells positive for: CK5/6, KL1, EGFR, some cells positive for CD117

numerous CD5-positive T-lymphocytes

ICD-O-3
Thymoma, type C 8586/3
Site Anterior mediastinum C38.1
4/7/14 JJS

Source: NCI Genomic Data Commons file 84dee50c-3cc1-48cd-ba77-5594aee4c961 (TCGA-ZB-A969.7E8A5F5C-E3E4-419B-95F7-EC15E465F226.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).